Gene-level copy-number profile of tumor specimen TCGA-44-3917-01B from TCGA case TCGA-44-3917, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 33.3 years (12,179 days).
Specimen TCGA-44-3917-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.9acca8b2-f51a-48a9-879f-c3af194cc1e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-3917-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/2ca93894-5912-48dd-9ac3-8829239419d4

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 27,488; copy number 2: 24,590; copy number 3: 7,096; copy number 4: 371; copy number 5: 190.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-3917-01A-01D-A273-01): tumor purity 0.38, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:16,714,844–17,735,871, 20 genes (within-gene range 0–3): AL034428.1, SNRPB2, OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2.
- chr21:10,328,411–14,658,821, 60 genes: AP003900.1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2, LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 7,656 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,630,335–121,580,524, 1,683 genes, copy number 3 (broad region; genes not listed).
- chr1:156,242,184–167,220,512, 355 genes, copy number 4 (broad region; genes not listed).
- chr1:168,695,468–232,630,571, 1,234 genes, copy number 3 (broad region; genes not listed).
- chr3:79,411,714–86,362,474, 40 genes, copy number 3–4: AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284.
- chr6:57,961,438–58,438,364, 1 gene, copy number 3 (within-gene range 1–3): AL445250.1.
- chr6:58,071,720–69,389,506, 63 genes, copy number 3 (broad region; genes not listed).
- chr6:69,705,287–69,746,851, 2 genes, copy number 3: NPM1P37, GAPDHP42.
- chr7:70,972–75,738,962, 1,422 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr7:77,798,792–108,569,666, 548 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr7:110,662,644–111,562,517, 1 gene, copy number 3 (within-gene range 1–3): IMMP2L.
- chr7:111,091,006–124,790,689, 175 genes, copy number 3 (broad region; genes not listed).
- chr8:41,653,220–41,896,762, 1 gene, copy number 3 (within-gene range 1–3): ANK1.
- chr8:41,803,349–145,066,685, 1,594 genes, copy number 3 (broad region; genes not listed).
- chr11:32,602,246–39,874,388, 96 genes, copy number 3 (broad region; genes not listed).
- chr14:34,740,336–48,819,593, 178 genes, copy number 5 (broad region; genes not listed).
- chr18:13,183,402–13,185,617, 1 gene, copy number 3: AP001198.2.
- chr18:37,473,330–44,071,701, 39 genes, copy number 3–5: AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1, AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, AC087683.3, LINC00907, RNA5SP454, AC084335.1, RIT2, AC100779.1, SYT4, AC022743.1, AC083760.1, RNA5SP455.
- chr18:67,081,584–80,247,514, 207 genes, copy number 3 (broad region; genes not listed).
- chr20:13,008,972–13,169,103, 1 gene, copy number 5 (within-gene range 1–14): SPTLC3.
- chr20:13,221,274–13,300,651, 3 genes, copy number 5: ISM1, ISM1-AS1, AL050320.1.
- chr20:16,177,933–16,684,404, 8 genes, copy number 3: AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1.
- chr20:19,208,652–19,722,926, 4 genes, copy number 5 (within-gene range 2–5): AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1.

Autosomal genes at a single copy (total copy number 1): 25,361. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
